Somatic mutation profile of tumor specimen TCGA-AD-6895-01A (aliquot TCGA-AD-6895-01A-11D-1924-10) from TCGA case TCGA-AD-6895, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 84.5 years (30,879 days).
Specimen TCGA-AD-6895-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b8e9ada-c568-461d-b8a8-f55a97a81801.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AD-6895-10A (Blood Derived Normal), aliquot TCGA-AD-6895-10A-01D-1924-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/816d5261-e0e9-4c55-bc94-aa9513dcfe70

The open-access MAF lists 1,970 somatic variants for this specimen: 1,431 protein-altering or splice-affecting, 503 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,111, Silent 503, Frame Shift Del 152, Nonsense Mutation 63, Frame Shift Ins 53, Splice Site 20, In Frame Del 18, RNA 14, Splice Region 14, Intron 9, 5'UTR 5, 3'UTR 4.

Variants (750 of 1,970; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC011462.1 | c.219del p.R74Gfs*23 | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | catalogued as rs398123489; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BARD1 | c.623del p.K208Rfs*4 | Frame Shift Del (DEL) | VAF 39/191 reads (20%) | catalogued as rs587780033; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BCOR | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 8/13 reads (62%) | catalogued as rs151177114, COSV60706923; ClinVar: pathogenic; called by mutect2, varscan2
- CHD8 | c.3322dup p.I1108Nfs*7 (on ENST00000646647 / NM_001170629.2; = p.I829Nfs*7 on NM_020920.4) | Frame Shift Ins (INS) | VAF 17/78 reads (22%) | catalogued as rs1157888951; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- COL2A1 | c.2219dup p.G741Wfs*29 | Frame Shift Ins (INS) | VAF 6/24 reads (25%) | catalogued as rs1565677720; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ERRFI1 | c.1227A>T p.K409N | Missense Mutation (SNP) | VAF 54/163 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs779337445, COSV66310415, COSV66310695; called by muse, mutect2, varscan2
- KRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 28/77 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as rs121913238, COSV55502066, COSV55502677; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.3261dup p.F1088Lfs*5 | Frame Shift Ins (INS) | VAF 28/134 reads (21%) | hotspot (GDC flag); catalogued as rs267608078; ClinVar: pathogenic; called by mutect2, varscan2
- OTC | c.613A>G p.M205V | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.589); catalogued as rs72558411, CM003036, COSV50001837; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RECQL4 | c.2161C>T p.R721* | Nonsense Mutation (SNP) | VAF 9/44 reads (20%) | catalogued as rs746691436, COSV52879546; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RHOA | c.206T>C p.L69P | Missense Mutation (SNP) | VAF 20/85 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV69041545, COSV69041670; called by muse, mutect2, varscan2
- TBX6 | c.704dup p.M236Hfs*44 | Frame Shift Ins (INS) | VAF 22/81 reads (27%) | catalogued as rs758051786; ClinVar: pathogenic; called by mutect2, varscan2
- AATK | c.139G>A p.V47I | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs759787297, COSV100452619; called by muse, mutect2, varscan2
- ABCA1 | c.3203G>A p.R1068H | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778885878, CM065953, COSV66064631, COSV66067035; called by muse, varscan2
- ABCA1 | c.3185G>A p.G1062D | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101036779, COSV66066638; called by muse, varscan2
- ABCA2 | c.3767C>T p.A1256V (on ENST00000614293; = p.A1226V on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV55801667; called by muse, mutect2, varscan2
- ABCC5 | c.1886C>T p.A629V | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV55590371; called by muse, mutect2, varscan2
- ABL2 | c.1586G>T p.R529M (on ENST00000502732 / NM_007314.4; = p.R514M on NM_005158.5) | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61014445; called by muse, mutect2, varscan2
- ABL2 | c.968C>T p.T323I (on ENST00000502732 / NM_007314.4; = p.T308I on NM_005158.5) | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV61014487; called by muse, mutect2, varscan2
- ABLIM3 | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs149749871; called by muse, mutect2, varscan2
- ABTB1 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51740490; called by muse, mutect2, varscan2
- ACACB | c.769del p.D257Ifs*17 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | catalogued as rs768607691; called by mutect2, pindel, varscan2
- ACAP3 | c.1099C>T p.R367C | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs765208758, COSV100685962; called by muse, mutect2, varscan2
- ACOT7 | c.761T>A p.M254K (on ENST00000377855 / NM_181864.3; = p.M244K on NM_007274.4) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV64113531; called by muse, mutect2, varscan2
- ACTG2 | c.1068G>A p.M356I | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as COSV61828381; called by muse, mutect2, varscan2
- ACTN3 | c.1885G>A p.D629N | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV100074054; called by muse, mutect2
- ACTR6 | c.704A>G p.D235G | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV51841855; called by muse, mutect2, varscan2
- ACTRT2 | c.1005del p.D336Tfs*16 | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | catalogued as rs1159784582; called by mutect2, pindel, varscan2
- ACVRL1 | c.830C>T p.T277M | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as rs750085854, CM159681, COSV66360207; called by muse, mutect2, varscan2
- ADAM33 | c.2303C>A p.P768H | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); catalogued as COSV62934831; called by muse, mutect2, varscan2
- ADAP2 | c.985G>A p.G329R | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1292639951, COSV58296004; called by muse, varscan2
- ADCK5 | c.809G>T p.G270V | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58233642; called by muse, mutect2, varscan2
- ADCY4 | c.1582del p.R528Gfs*3 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | catalogued as rs746788867; called by mutect2, pindel
- ADCY6 | c.2174C>T p.P725L | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57168011; called by muse, mutect2, varscan2
- ADD3 | c.134T>C p.L45P | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53322453; called by muse, mutect2, varscan2
- ADGRB1 | c.3733C>T p.R1245C | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs774138249, COSV60096863; called by muse, mutect2, varscan2
- ADGRB2 | c.4496G>A p.R1499H (on ENST00000373658 / NM_001364857.2; = p.R1498H on NM_001294335.2) | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs749337394, COSV57073407; called by muse, mutect2, varscan2
- ADGRB2 | c.649G>A p.G217S | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.28); catalogued as rs747551189, COSV57073758; called by muse, mutect2, varscan2
- ADGRE3 | c.571A>G p.S191G | Missense Mutation (SNP) | VAF 75/213 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV53730740; called by muse, mutect2, varscan2
- ADGRL1 | c.2944G>A p.A982T (on ENST00000340736 / NM_001008701.3; = p.A977T on NM_014921.5) | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.6); catalogued as COSV100529208; called by muse, mutect2
- ADGRL1 | c.1060C>T p.R354C (on ENST00000340736 / NM_001008701.3; = p.R349C on NM_014921.5) | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs144793304; called by muse, mutect2, varscan2
- ADGRV1 | c.15271del p.Y5091Tfs*7 | Frame Shift Del (DEL) | VAF 15/62 reads (24%) | catalogued as rs1435790810; called by mutect2, pindel, varscan2
- ADPRHL1 | c.469G>A p.V157M | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as rs770530487, COSV62910249; called by muse, mutect2, varscan2
- AFF3 | c.1822C>T p.P608S | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.21); PolyPhen benign (0.272); catalogued as COSV100417235; called by muse, mutect2, varscan2
- AFF4 | c.2464A>T p.K822* | Nonsense Mutation (SNP) | VAF 32/92 reads (35%) | catalogued as COSV54794845; called by muse, mutect2, varscan2
- AGFG1 | c.1634G>A p.G545D | Missense Mutation (SNP) | VAF 54/191 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV59512105; called by muse, mutect2, varscan2
- AGL | c.316T>A p.Y106N | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54052876, COSV99649072; called by muse, mutect2, varscan2
- AHDC1 | c.668C>T p.T223M | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.706); catalogued as rs764325293, COSV55939066; called by muse, mutect2, varscan2
- AIFM1 | c.1720G>A p.V574M | Missense Mutation (SNP) | VAF 27/39 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54854850; called by muse, mutect2, varscan2
- AKAP11 | c.1454A>G p.Y485C | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV50297091; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 52/196 reads (27%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- ALDH1A1 | c.1093G>A p.G365R | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV52791412; called by muse, mutect2, varscan2
- ALDH1B1 | c.646del p.L216Sfs*20 | Frame Shift Del (DEL) | VAF 4/21 reads (19%) | catalogued as rs759954510; called by mutect2, pindel
- ALKBH4 | c.170G>A p.G57D | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.163); catalogued as COSV52961007; called by muse, mutect2, varscan2
- ALKBH5 | c.1168A>G p.K390E | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV101213221; called by muse, mutect2, varscan2
- ALOX5 | c.965T>C p.V322A | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV100979920; called by muse, mutect2, varscan2
- AMER1 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as rs756142618, COSV57661017; called by muse, mutect2, varscan2
- AMER2 | c.1886C>T p.P629L | Missense Mutation (SNP) | VAF 14/171 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.03); catalogued as COSV100766366, COSV63437634; called by muse, mutect2
- AMPD2 | c.1793A>C p.D598A | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.071); catalogued as COSV99857285; called by muse, mutect2, varscan2
- ANGPTL2 | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs201706693, COSV52222225; called by muse, mutect2, varscan2
- ANKAR | c.2749A>T p.K917* | Nonsense Mutation (SNP) | VAF 34/127 reads (27%) | catalogued as COSV55612963; called by muse, mutect2, varscan2
- ANKRD10 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.752); catalogued as rs368912394; called by muse, mutect2, varscan2
- ANO3 | c.358A>G p.T120A | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs1009310778, COSV56791615; called by muse, mutect2, varscan2
- ANO6 | c.1367C>T p.A456V | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.023); catalogued as rs1272161801, COSV57657063; called by muse, mutect2, varscan2
- ANO9 | c.976T>C p.S326P | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60449366; called by muse, mutect2, varscan2
- ANP32B | c.623A>G p.E208G | Missense Mutation (SNP) | VAF 59/163 reads (36%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.932); catalogued as COSV59586702; called by muse, mutect2, varscan2
- AP002748.5 | c.22T>A p.S8T | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV59148927; called by muse, mutect2, varscan2
- AP2M1 | c.139G>A p.V47I | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.114); catalogued as rs777567779, COSV53048135; called by muse, mutect2, varscan2
- AP3M2 | c.672C>T p.N224= | Splice Region (SNP) | VAF 43/138 reads (31%) | catalogued as COSV51528898; called by muse, mutect2, varscan2
- AP5Z1 | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs752280716, COSV62241892; called by muse, mutect2, varscan2
- APBA2 | c.1280C>T p.T427M | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs375339761; called by muse, mutect2, varscan2
- APBB1 | c.1841T>C p.V614A | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100192240; called by muse, mutect2
- APBB1IP | c.100C>G p.P34A | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as COSV63302622; called by muse, mutect2, varscan2
- APCDD1L | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.731); catalogued as rs776772090, COSV100953874; called by muse, mutect2, varscan2
- ARGLU1 | c.473T>A p.L158H | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV62271574; called by muse, mutect2, varscan2
- ARHGAP18 | c.1208T>C p.L403P | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100935995; called by muse, mutect2, varscan2
- ARHGAP19 | c.937T>C p.Y313H | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV57393074; called by muse, mutect2, varscan2
- ARHGAP35 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.265); catalogued as COSV101350639; called by muse, mutect2, varscan2
- ARHGAP35 | c.3748C>T p.P1250S | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101350641; called by muse, mutect2, varscan2
- ARHGAP39 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.608); catalogued as rs868436060, COSV52770419; called by muse, mutect2, varscan2
- ARHGEF10 | c.668C>T p.A223V (on ENST00000398564; = p.A198V on NM_014629.4) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.018); catalogued as COSV50650925; called by muse, mutect2, varscan2
- ARHGEF10 | c.1656T>A p.D552E (on ENST00000398564; = p.D527E on NM_014629.4) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50650991; called by muse, mutect2, varscan2
- ARHGEF17 | c.1285C>T p.R429W | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.009); catalogued as rs1232213384, COSV55232683; called by muse, mutect2, varscan2
- ARHGEF18 | c.3164G>A p.R1055K (on ENST00000359920 / NM_001130955.2; = p.R951K on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV60470019; called by muse, mutect2, varscan2
- ARHGEF25 | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs138453741; called by muse, mutect2, varscan2
- ARHGEF7 | c.1003G>A p.E335K (on ENST00000375741 / NM_001113511.2; = p.E157K on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV54539485, COSV54543633; called by muse, mutect2, varscan2
- ARID1A | c.6529G>A p.G2177R | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61378086; called by muse, mutect2, varscan2
- ARID1B | c.4444C>T p.R1482C | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.791); catalogued as COSV51662228; called by muse, mutect2, varscan2
- ARID2 | c.3205_3207del p.G1069del | In Frame Del (DEL) | VAF 10/60 reads (17%) | catalogued as rs1173958153; called by mutect2, pindel
- ARID4B | c.2809A>T p.K937* | Nonsense Mutation (SNP) | VAF 30/89 reads (34%) | catalogued as COSV51598811, COSV51603494; called by muse, mutect2, varscan2
- ARID5B | c.138T>A p.C46* | Nonsense Mutation (SNP) | VAF 11/60 reads (18%) | catalogued as COSV54420824; called by muse, mutect2, varscan2
- ARL10 | c.692G>A p.G231D | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.044); catalogued as COSV100118944; called by muse, varscan2
- ASB18 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.68); PolyPhen benign (0.079); catalogued as COSV58233932; called by muse, mutect2, varscan2
- ATAD1 | c.910C>T p.R304* | Nonsense Mutation (SNP) | VAF 28/108 reads (26%) | catalogued as rs1183753874, COSV57755834; called by muse, mutect2, varscan2
- ATG2A | c.3223C>T p.R1075C | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1299595904, COSV65966919; called by muse, mutect2, varscan2
- ATG4B | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.49); catalogued as rs752539092, COSV60351044; called by muse, varscan2
- ATN1 | c.893C>T p.T298I | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); catalogued as COSV63111096; called by muse, mutect2, varscan2
- ATP2A1 | c.1961C>T p.T654M | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs148957878; called by muse, mutect2, varscan2
- ATP2C2 | c.2008G>A p.A670T | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV52296254; called by muse, mutect2, varscan2
- ATP6V0D1 | c.994A>T p.I332F | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV52098078; called by muse, mutect2, varscan2
- AZIN2 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs144776558; called by muse, mutect2, varscan2
- BACE2 | c.1334C>T p.S445F | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.639); catalogued as COSV57739721; called by muse, mutect2, varscan2
- BAHCC1 | c.1874C>T p.A625V | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.3); catalogued as rs782618003, COSV57026959; called by muse, mutect2, varscan2
- BAHCC1 | c.3110A>T p.E1037V | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.283); catalogued as COSV57026978; called by muse, mutect2, varscan2
- BAHCC1 | c.4541C>T p.A1514V | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.559); catalogued as rs1294495291, COSV57026991; called by muse, mutect2, varscan2
- BAIAP2 | c.314T>C p.L105P | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100347306, COSV100347477; called by muse, mutect2, varscan2
- BAIAP3 | c.2353C>T p.R785W | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as rs143578932; called by muse, mutect2, varscan2
- BARHL2 | c.695C>T p.P232L | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs868229360, COSV64981290; called by mutect2, varscan2
- BBS9 | c.1381G>A p.V461M | Missense Mutation (SNP) | VAF 51/223 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as rs780524334, COSV54168610; called by muse, mutect2, varscan2
- BCL9L | c.2432G>A p.G811D | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.927); catalogued as COSV52684568; called by muse, mutect2, varscan2
- BCORL1 | c.1494G>T p.E498D | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as COSV54396680; called by muse, mutect2, varscan2
- BEND4 | c.1474G>A p.G492S | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs751788865, COSV72469040; called by muse, mutect2, varscan2
- BHLHA15 | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.022); catalogued as rs754124873, COSV99805824; called by mutect2, varscan2
- BIN2 | c.1444A>T p.K482* | Nonsense Mutation (SNP) | VAF 76/249 reads (31%) | catalogued as COSV57205421; called by muse, mutect2, varscan2
- BIN2 | c.1229C>T p.T410I | Missense Mutation (SNP) | VAF 52/168 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.157); catalogued as COSV57205428; called by muse, mutect2, varscan2
- BLM | c.2313T>A p.C771* | Nonsense Mutation (SNP) | VAF 28/146 reads (19%) | catalogued as COSV61924165; called by muse, mutect2, varscan2
- BMP1 | c.1839del p.N614Tfs*138 (on ENST00000306385 / NM_006129.5; = p.N614Tfs*188 on NM_001199.4) | Frame Shift Del (DEL) | VAF 9/26 reads (35%) | catalogued as rs758822270; called by mutect2, pindel, varscan2
- BMP2K | c.1367G>A p.R456H | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs374800739; called by muse, mutect2, varscan2
- BMPR2 | c.846T>A p.Y282* | Nonsense Mutation (SNP) | VAF 14/52 reads (27%) | catalogued as COSV65809544; called by muse, mutect2, varscan2
- BMS1 | c.3227G>A p.R1076Q | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.687); catalogued as rs756311685, COSV65733956; called by muse, mutect2, varscan2
- BMS1 | c.3748C>T p.R1250W | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs775825569, COSV65733959; called by muse, mutect2, varscan2
- BNC1 | c.947A>G p.D316G | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.494); catalogued as rs1193153863, COSV61757491; called by muse, mutect2, varscan2
- BNC1 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61757496; called by muse, mutect2, varscan2
- BOK | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as rs750227285, COSV59192497; called by muse, mutect2, varscan2
- BRAF | c.1645C>T p.R549* (on ENST00000288602 / NM_001374244.1; = p.R509* on NM_004333.6 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 10/39 reads (26%) | catalogued as rs1485437761, COSV56181083; called by muse, mutect2, varscan2
- BRD4 | c.3776G>A p.R1259H | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as rs1422529717, COSV54586387, COSV54595539; called by muse, mutect2, varscan2
- BRWD1 | c.4664C>T p.S1555F | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.157); catalogued as COSV60896221; called by muse, mutect2, varscan2
- BRWD3 | c.3238A>T p.S1080C | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64748408; called by muse, mutect2, varscan2
- BZW2 | c.158A>G p.D53G | Missense Mutation (SNP) | VAF 13/149 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV51755162; called by muse, mutect2
- C14orf28 | c.622G>T p.G208C | Missense Mutation (SNP) | VAF 60/202 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.029); catalogued as COSV57333378; called by muse, varscan2
- C15orf39 | c.2752C>T p.R918C | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1317526889, COSV62296754, COSV62298266; called by muse, mutect2, varscan2
- C17orf80 | c.1111T>A p.S371T | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); catalogued as COSV52146568; called by muse, mutect2, varscan2
- C9orf16 | c.210C>A p.F70L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.77); catalogued as COSV52971506; called by muse, mutect2, varscan2
- CA14 | c.268_269del p.L90Afs*38 | Frame Shift Del (DEL) | VAF 13/57 reads (23%) | catalogued as rs1162215409; called by pindel, varscan2
- CA4 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs200180434, COSV56281554; called by muse, mutect2, varscan2
- CA6 | c.22C>A p.L8M | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.871); catalogued as COSV66262162; called by muse, mutect2, varscan2
- CABIN1 | c.461A>T p.N154I | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54081996; called by muse, mutect2, varscan2
- CACNA1B | c.1430G>A p.R477H | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs1037362457, COSV53113700; called by muse, mutect2, varscan2
- CACNA1D | c.28del p.M10Cfs*60 | Frame Shift Del (DEL) | VAF 24/141 reads (17%) | catalogued as COSV55457798; called by mutect2, varscan2
- CACNA1H | c.1420C>T p.R474C | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1169352200, COSV61991076; called by muse, mutect2, varscan2
- CACNA2D1 | c.1040A>G p.Y347C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.748); catalogued as COSV62379954; called by muse, mutect2, varscan2
- CACNA2D2 | c.2227C>T p.R743C (on ENST00000479441 / NM_001174051.3; = p.R736C on NM_006030.4) | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as COSV56561356; called by muse, mutect2, varscan2
- CAMK1D | c.1145C>T p.S382F | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); catalogued as COSV66611716; called by muse, mutect2, varscan2
- CAMK2A | c.1255A>G p.I419V (on ENST00000348628 / NM_171825.2; = p.I430V on NM_015981.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); catalogued as COSV62246450; called by muse, mutect2, varscan2
- CAMKK1 | c.455G>A p.R152K | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as COSV50117084; called by muse, mutect2, varscan2
- CASD1 | c.94C>A p.L32M | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.725); catalogued as COSV99802177; called by muse, mutect2
- CASP5 | c.88G>A p.V30M | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); catalogued as rs748713070, COSV52828692; called by muse, varscan2
- CASP8 | c.1279C>T p.Q427* (on ENST00000432109 / NM_033355.3; = p.Q444* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 8/20 reads (40%) | catalogued as COSV51851265; called by muse, mutect2, varscan2
- CASR | c.1814C>T p.P605L (on ENST00000490131; = p.P682L on NM_000388.4) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.938); catalogued as rs1553768989, CM102309, COSV56137331; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CASZ1 | c.3310G>A p.A1104T | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201167368; called by muse, mutect2, varscan2
- CATSPER4 | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs149779483; called by muse, mutect2, varscan2
- CATSPERB | c.1954A>G p.T652A | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.121); catalogued as COSV56426694; called by muse, mutect2, varscan2
- CAVIN1 | c.875C>T p.T292M | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.681); catalogued as rs1370778063, COSV63811883; called by muse, mutect2, varscan2
- CAVIN1 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.035); catalogued as COSV63811889; called by muse, mutect2, varscan2
- CC2D2A | c.1399C>T p.P467S | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV101052631; called by muse, mutect2, varscan2
- CC2D2A | c.1482C>A p.F494L | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101052632, COSV67502278; called by muse, mutect2, varscan2
- CCAR2 | c.47G>A p.R16H | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.976); catalogued as COSV51515309; called by muse, mutect2, varscan2
- CCDC105 | c.1148C>T p.S383L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as COSV52963627; called by muse, mutect2, varscan2
- CCDC116 | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs755475376, COSV53040594; called by muse, mutect2, varscan2
- CCDC15 | c.2563C>T p.Q855* | Nonsense Mutation (SNP) | VAF 52/242 reads (21%) | catalogued as COSV61081954, COSV61083659; called by muse, mutect2, varscan2
- CCDC40 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.434); catalogued as rs775299709, COSV53899659; called by muse, mutect2, varscan2
- CCDC40 | c.1861G>A p.E621K | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.649); catalogued as rs752125203, COSV66474974; called by muse, mutect2, varscan2
- CCDC88C | c.4238A>T p.K1413I | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58661567; called by muse, mutect2, varscan2
- CCDC89 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as rs753113157, COSV57034021; called by muse, mutect2, varscan2
- CCNT1 | c.393A>T p.Q131H | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV56064277; called by muse, mutect2, varscan2
- CCT4 | c.918-2A>G p.X306_splice | Splice Site (SNP) | VAF 20/62 reads (32%) | catalogued as COSV66701465; called by muse, mutect2, varscan2
- CCT8 | c.1525A>G p.K509E | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as rs1473131027, COSV54504068; called by muse, mutect2, varscan2
- CD164 | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.821); catalogued as COSV51533552; called by muse, mutect2, varscan2
- CD209 | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs368570264; called by muse, mutect2, varscan2
- CD248 | c.1278G>T p.E426D | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV60936527; called by muse, mutect2, varscan2
- CD8A | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs138963205, COSV52157522; called by muse, mutect2, varscan2
- CDC34 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.191); catalogued as COSV53116787; called by muse, mutect2, varscan2
- CDC42EP2 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1021807508, COSV54203416; called by muse, mutect2, varscan2
- CDC5L | c.2059G>A p.D687N | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as COSV65176110; called by muse, mutect2, varscan2
- CDH4 | c.1141A>G p.T381A | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.072); catalogued as COSV64655274; called by muse, mutect2, varscan2
- CDHR1 | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60562475; called by muse, mutect2, varscan2
- CDK19 | c.436T>C p.W146R | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100097864; called by muse, mutect2, varscan2
- CDK9 | c.793C>G p.L265V | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as rs1436815577, COSV64723792; called by muse, mutect2
- CDKN1A | c.142C>T p.R48* | Nonsense Mutation (SNP) | VAF 8/18 reads (44%) | catalogued as rs1407742055, COSV55187604; called by muse, mutect2, varscan2
- CDKN2AIP | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs772080485, COSV56627225; called by muse, mutect2, varscan2
- CDYL2 | c.354del p.Y120Ifs*27 | Frame Shift Del (DEL) | VAF 13/63 reads (21%) | catalogued as COSV101629564; called by mutect2, varscan2
- CEACAM19 | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs755153473, COSV100715377, COSV62552032; called by muse, mutect2
- CELSR1 | c.1888T>C p.F630L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV99416445; called by muse, mutect2, varscan2
- CELSR2 | c.6124C>T p.R2042W | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs756134624, COSV54772279; called by muse, varscan2
- CELSR2 | c.6229G>A p.A2077T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.684); catalogued as COSV99602864; called by muse, varscan2
- CELSR3 | c.3400G>A p.A1134T | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.99); PolyPhen benign (0.015); catalogued as COSV99372291; called by muse, mutect2, varscan2
- CEP152 | c.2984C>T p.A995V | Missense Mutation (SNP) | VAF 65/250 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.329); catalogued as rs146955708; called by muse, mutect2, varscan2
- CEP152 | c.1575C>A p.T525= | Splice Region (SNP) | VAF 35/133 reads (26%) | catalogued as COSV57859603; called by muse, mutect2, varscan2
- CEP164 | c.2669G>A p.R890H | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs368178224, COSV54044571; called by muse, mutect2, varscan2
- CEP170B | c.1915C>T p.P639S (on ENST00000453495; = p.P568S on NM_015005.3) | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.05); catalogued as rs770766563, COSV101371371; called by muse, mutect2
- CEP250 | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as COSV61170296; called by muse, mutect2, varscan2
- CFAP47 | c.4863A>C p.E1621D | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.712); catalogued as COSV100544819; called by muse, mutect2, varscan2
- CFAP77 | c.686T>C p.V229A | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.318); catalogued as rs1405361696, COSV58011249; called by muse, mutect2, varscan2
- CFL1 | c.472G>A p.V158I | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.03); catalogued as COSV57449405; called by muse, mutect2, varscan2
- CHD2 | c.3038C>G p.A1013G | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.076); catalogued as COSV67709599; called by muse, varscan2
- CHD3 | c.5786C>T p.P1929L (on ENST00000330494 / NM_001005273.3; = p.P1895L on NM_005852.4) | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs561278276, COSV57875301; called by muse, mutect2, varscan2
- CHD7 | c.3763C>T p.P1255S | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764970349, COSV71110769; called by muse, mutect2, varscan2
- CHL1 | c.710T>G p.L237R (on ENST00000397491 / NM_001253387.1; = p.L253R on NM_006614.4) | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as COSV56593808; called by muse, mutect2, varscan2
- CHRD | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs980833271, COSV52608137; called by muse, mutect2, varscan2
- CHST2 | c.571T>C p.F191L | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58885581; called by muse, mutect2, varscan2
- CHST2 | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58885590; called by muse, mutect2, varscan2
- CHST2 | c.1153G>A p.G385S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.99); catalogued as COSV58885598; called by muse, mutect2, varscan2
- CHST3 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as rs767508669, COSV100910368; called by muse, mutect2, varscan2
- CHST3 | c.986G>C p.G329A | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); catalogued as COSV100910369; called by muse, mutect2, varscan2
- CHST6 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.616); catalogued as COSV60000181; called by muse, mutect2, varscan2
- CIB2 | c.198+2T>C p.X66_splice | Splice Site (SNP) | VAF 6/33 reads (18%) | catalogued as COSV51948566; called by muse, mutect2, varscan2
- CILP | c.1550T>C p.V517A | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.13); catalogued as COSV99972674; called by muse, mutect2
- CILP2 | c.121G>A p.V41M | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as rs1568368595, COSV52275092; called by muse, mutect2, varscan2
- CIPC | c.1137A>T p.L379F | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62376993; called by muse, mutect2, varscan2
- CKAP2 | c.1817del p.K606Rfs*14 (on ENST00000378037 / NM_001098525.2; = p.K605Rfs*14 on NM_018204.5) | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | catalogued as rs752250702; called by mutect2, varscan2
- CLASP2 | c.1807C>T p.R603* | Nonsense Mutation (SNP) | VAF 17/49 reads (35%) | catalogued as COSV56282890; called by muse, mutect2, varscan2
- CLEC12B | c.186G>A p.M62I | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58862966; called by muse, mutect2
- CLEC4D | c.606A>T p.E202D | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.751); catalogued as COSV55229064; called by muse, mutect2, varscan2
- CLIP2 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1170985729, COSV56278897; called by muse, varscan2
- CLPTM1L | c.1498G>A p.D500N | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1346369634, COSV57990583; called by muse, mutect2, varscan2
- CLSTN2 | c.1653A>T p.E551D | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.787); catalogued as COSV71720952; called by muse, mutect2, varscan2
- CLTB | c.646C>T p.R216C (on ENST00000310418 / NM_007097.5; = p.R198C on NM_001834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757930059, COSV51257639; called by muse, mutect2, varscan2
- CLTC | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs1344484363, COSV52244894; called by muse, mutect2, varscan2
- CLUH | c.2360G>A p.R787H (on ENST00000435359; = p.R826H on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1268969803, COSV70928007; called by muse, mutect2, varscan2
- CMPK1 | c.549-2A>G p.X183_splice | Splice Site (SNP) | VAF 15/50 reads (30%) | catalogued as COSV64101908; called by muse, mutect2, varscan2
- CNKSR1 | c.1535del p.P512Hfs*58 (on ENST00000374253 / NM_001297647.2; = p.P505Hfs*58 on NM_006314.3) | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as rs753922055; called by mutect2, pindel, varscan2
- CNKSR3 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.368); catalogued as rs769098143, COSV72161748; called by muse, mutect2, varscan2
- CNNM1 | c.1404G>T p.E468D | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.05); catalogued as COSV63201704; called by muse, mutect2, varscan2
- CNNM1 | c.1505A>T p.Y502F | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV63201711; called by muse, mutect2, varscan2
- CNOT1 | c.2706del p.Q904Sfs*9 | Frame Shift Del (DEL) | VAF 22/86 reads (26%) | catalogued as rs1397135931, COSV55313852; called by mutect2, varscan2
- CNTN1 | c.1510C>T p.P504S | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1035789342, COSV61636046; called by muse, mutect2, varscan2
- CNTNAP1 | c.2285C>T p.T762M | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs565230756, COSV52850699; called by muse, mutect2, varscan2
- CNTNAP4 | c.863T>A p.V288E | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56681243; called by muse, mutect2, varscan2
- CNTRL | c.3203C>T p.T1068I | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.08); catalogued as COSV53047296; called by muse, mutect2, varscan2
- COA6 | c.91G>A p.G31S | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.007); catalogued as COSV64016837; called by muse, mutect2, varscan2
- COL11A1 | c.4273G>A p.A1425T | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.197); catalogued as COSV62184054; called by muse, mutect2, varscan2
- COL11A2 | c.4393-1G>T p.X1465_splice (on ENST00000341947 / NM_080680.3; = p.X1358_splice on NM_080679.2) | Splice Site (SNP) | VAF 7/16 reads (44%) | catalogued as COSV100553324; called by muse, mutect2, varscan2
- COL14A1 | c.4702C>T p.P1568S | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.809); catalogued as COSV52854901; called by muse, mutect2, varscan2
- COL17A1 | c.3469C>T p.P1157S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.94); catalogued as COSV62225159; called by muse, mutect2, varscan2
- COL17A1 | c.1576G>T p.G526C | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV62226835; called by muse, mutect2, varscan2
- COL19A1 | c.265A>G p.I89V | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV59573791; called by muse, mutect2, varscan2
- COL1A2 | c.2686C>T p.P896S | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV51958479; called by muse, mutect2, varscan2
- COL20A1 | c.2738G>A p.R913H | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); catalogued as rs201266100; called by muse, mutect2, varscan2
- COL25A1 | c.643G>T p.D215Y | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as rs1205668803, COSV67646944; called by muse, mutect2, varscan2
- COL2A1 | c.3329G>A p.G1110D | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV61530838; called by muse, mutect2, varscan2
- COL4A1 | c.2869+2C>T p.X957_splice | Splice Site (SNP) | VAF 5/23 reads (22%) | catalogued as COSV101010916; called by muse, mutect2, varscan2
- COL4A3 | c.2737G>T p.G913W | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1414049, COSV101169779, COSV67420284; called by muse, mutect2
- COL5A1 | c.663C>G p.I221M | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV65669189; called by muse, mutect2, varscan2
- COL7A1 | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs760362837, COSV60401262; called by muse, mutect2, varscan2
- COL8A2 | c.1172G>A p.G391D | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57441816; called by muse, mutect2, varscan2
- COLGALT1 | c.667C>T p.R223* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as rs888552889, COSV53109286; called by muse, mutect2, varscan2
- CORO2B | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs775165158, COSV99962817; called by muse, mutect2, varscan2
- COX10 | c.847G>C p.A283P | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.726); catalogued as COSV55405134; called by muse, mutect2, varscan2
- COX6B1 | c.169T>C p.Y57H | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.582); catalogued as COSV55837814; called by muse, varscan2
- CPB1 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs142211299; called by muse, mutect2, varscan2
- CPNE8 | c.1142T>A p.L381* | Nonsense Mutation (SNP) | VAF 14/67 reads (21%) | catalogued as COSV58843518; called by muse, mutect2, varscan2
- CPPED1 | c.266G>A p.G89D | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55497813; called by muse, mutect2, varscan2
- CPQ | c.740C>A p.S247Y | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as COSV55146212, COSV55149513; called by muse, mutect2, varscan2
- CPSF1 | c.958A>T p.I320F | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as COSV62940301; called by muse, mutect2, varscan2
- CPT1C | c.1808G>A p.R603Q | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201154568, COSV54919293; called by muse, mutect2, varscan2
- CR1 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as rs536471861, COSV65455515, COSV65457531; called by muse, mutect2, varscan2
- CREB5 | c.1121C>T p.P374L (on ENST00000357727 / NM_182898.4; = p.P367L on NM_004904.3) | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63221043; called by muse, varscan2
- CRY1 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772585429, COSV50482974; called by muse, mutect2, varscan2
- CRYZL1 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.036); catalogued as rs763694929, COSV51677627; called by muse, mutect2, varscan2
- CSF2RA | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as rs777638014, COSV62623722; called by muse, mutect2, varscan2
- CSMD1 | c.8186G>A p.G2729E (on ENST00000520002; = p.G2728E on NM_033225.6) | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV59309668, COSV59326540, COSV59404554; called by muse, mutect2, varscan2
- CSMD1 | c.6533C>T p.T2178M (on ENST00000520002; = p.T2177M on NM_033225.6) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.841); catalogued as rs762177917, COSV59326562; called by muse, mutect2, varscan2
- CSMD1 | c.5913C>A p.C1971* (on ENST00000520002; = p.C1970* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 21/102 reads (21%) | catalogued as COSV100142228; called by muse, mutect2, varscan2
- CSMD1 | c.5519G>A p.G1840E (on ENST00000520002; = p.G1839E on NM_033225.6) | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59287884; called by muse, mutect2, varscan2
- CSMD2 | c.5304G>T p.Q1768H | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.905); catalogued as COSV53914035; called by muse, mutect2, varscan2
- CSMD3 | c.8543G>A p.R2848Q (on ENST00000297405 / NM_001363185.1; = p.R2679Q on NM_052900.3) | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs201914089, COSV52185659, COSV52305294; called by mutect2, varscan2
- CSMD3 | c.2047C>T p.R683C (on ENST00000297405 / NM_001363185.1; = p.R579C on NM_052900.3) | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1266203286, COSV52185681; called by muse, mutect2, varscan2
- CSMD3 | c.139T>C p.W47R | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.467); catalogued as COSV52353306; called by muse, varscan2
- CTBS | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.127); catalogued as rs780281748, COSV55362495; called by muse, mutect2, varscan2
- CTNNA1 | c.1652G>T p.R551L | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100242009; called by muse, mutect2, varscan2
- CTNND1 | c.2339A>T p.N780I (on ENST00000399050 / NM_001085458.2; = p.N774I on NM_001331.3) | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV62383541; called by muse, mutect2, varscan2
- CTSF | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs142782021, COSV59748742; called by muse, mutect2, varscan2
- CTSW | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.67); PolyPhen benign (0.107); catalogued as rs777175870, COSV57172384; called by muse, mutect2, varscan2
- CUX2 | c.4447G>A p.E1483K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV55632735, COSV55636357; called by muse, mutect2, varscan2
- CYFIP1 | c.1366G>A p.A456T | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.604); catalogued as rs759931816; called by muse, mutect2
- CYP2A13 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs148044792, CM067778, COSV57836963; called by muse, mutect2, varscan2
- CYP2C19 | c.995G>A p.G332D | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64907808; called by muse, mutect2, varscan2
- CYP4A22 | c.1345C>T p.P449S | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53740280; called by muse, mutect2, varscan2
- CYP4F2 | c.457C>A p.P153T | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1449702446, COSV99171034; called by muse, mutect2, varscan2
- CYP4Z1 | c.1180G>A p.D394N | Missense Mutation (SNP) | VAF 64/193 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100497486; called by muse, varscan2
- CYP8B1 | c.742_744del p.K248del | In Frame Del (DEL) | VAF 15/44 reads (34%) | catalogued as rs750438995; called by mutect2, pindel, varscan2
- DAAM2 | c.2455G>A p.G819R | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51321336; called by muse, mutect2
- DAB2IP | c.2732C>T p.A911V (on ENST00000408936; = p.A883V on NM_032552.3) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.946); catalogued as COSV52259952; called by muse, mutect2, varscan2
- DAZAP1 | c.770del p.P257Rfs*78 | Frame Shift Del (DEL) | VAF 24/66 reads (36%) | catalogued as COSV99245498; called by mutect2, pindel, varscan2
- DCAF1 | c.433A>G p.T145A | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.055); catalogued as COSV60043028; called by muse, mutect2, varscan2
- DCAF11 | c.1331G>A p.R444Q | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.749); catalogued as rs1188300710, COSV58109240, COSV58110245; called by muse, mutect2, varscan2
- DCAF6 | c.245G>A p.S82N | Missense Mutation (SNP) | VAF 39/196 reads (20%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV56578978; called by muse, mutect2, varscan2
- DCDC1 | c.4453C>A p.Q1485K (on ENST00000597505 / NM_001367979.1; = p.Q592K on NM_020869.3) | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.024); catalogued as COSV57999365; called by muse, mutect2, varscan2
- DCHS2 | n.2651A>T | Splice Region (SNP) | VAF 8/40 reads (20%) | catalogued as COSV59726917; called by muse, mutect2, varscan2
- DCLK1 | c.217G>A p.V73M | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); catalogued as COSV99708700; called by muse, varscan2
- DCST1 | c.700C>A p.L234M | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV99792604; called by muse, varscan2
- DDN | c.1411C>T p.R471* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as COSV100304819, COSV60291723; called by muse, mutect2
- DDR1 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as rs749476480, COSV61321291; called by muse, mutect2
- DDX39A | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); catalogued as COSV54391703; called by muse, mutect2, varscan2
- DDX47 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.166); catalogued as COSV61911459; called by muse, mutect2, varscan2
- DDX55 | c.515A>C p.E172A | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53016172; called by muse, mutect2, varscan2
- DDX59 | c.479C>A p.S160Y | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.129); catalogued as COSV58752120; called by muse, mutect2, varscan2
- DEPDC5 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760668998, CM164374, COSV56690476; called by muse, mutect2, varscan2
- DGCR8 | c.1705+2T>C p.X569_splice | Splice Site (SNP) | VAF 5/35 reads (14%) | catalogued as COSV100707760; called by muse, mutect2, varscan2
- DGUOK | c.356T>A p.L119Q | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51203666; called by mutect2, varscan2
- DHX30 | c.2408T>C p.M803T (on ENST00000445061 / NM_138615.3; = p.M764T on NM_014966.3) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV99274541; called by muse, mutect2, varscan2
- DHX30 | c.3170T>A p.L1057Q (on ENST00000445061 / NM_138615.3; = p.L1018Q on NM_014966.3) | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV53137812, COSV99274678; called by muse, varscan2
- DHX34 | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1430732188, COSV100169157; called by muse, mutect2
- DIPK2A | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV100237042; called by muse, mutect2
- DLGAP3 | c.1576G>A p.A526T | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV99332043; called by muse, mutect2, varscan2
- DMBT1 | c.6319C>T p.R2107C (on ENST00000338354 / NM_001377530.1; = p.R1350C on NM_004406.3) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); catalogued as rs747972203, COSV57544508; called by muse, varscan2
- DMD | c.1483-2A>G p.X495_splice | Splice Site (SNP) | VAF 40/73 reads (55%) | catalogued as CS115786, COSV55872446; called by muse, mutect2, varscan2
- DMXL1 | c.2495T>A p.V832D | Missense Mutation (SNP) | VAF 16/177 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV100223043; called by muse, mutect2
- DMXL1 | c.4124C>T p.T1375I | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.133); catalogued as rs1042657541, COSV60711911; called by muse, mutect2, varscan2
- DNAAF2 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV53569375; called by muse, mutect2, varscan2
- DNAAF6 | c.400T>G p.S134A | Missense Mutation (SNP) | VAF 57/111 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV60495888; called by muse, mutect2, varscan2
- DNAH10 | c.6005G>A p.R2002H (on ENST00000409039; = p.R1941H on NM_207437.3) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755158563, COSV68994154; called by muse, mutect2, varscan2
- DNAH10 | c.9451G>A p.A3151T (on ENST00000409039; = p.A3090T on NM_207437.3) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs755170340, COSV68994162; called by muse, mutect2, varscan2
- DNAH11 | c.2426G>A p.C809Y | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.073); catalogued as rs540459682, COSV60956454; called by muse, mutect2, varscan2
- DNAH2 | c.1787G>A p.R596Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.608); catalogued as rs752231674, COSV50014720; called by muse, mutect2, varscan2
- DNAH8 | c.12226G>A p.E4076K | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773290369, COSV59433599; called by muse, mutect2, varscan2
- DNAH9 | c.8189A>G p.K2730R | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.033); catalogued as COSV52340561, COSV52350404; called by muse, mutect2, varscan2
- DNAI1 | c.1987C>T p.R663C | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs564706097, CM085363, COSV54280454; ClinVar: uncertain significance; called by muse, mutect2
- DNAJA1 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58309784; called by muse, mutect2, varscan2
- DNAJC15 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.997); catalogued as rs759741311, COSV64872274; called by muse, mutect2, varscan2
- DNAJC21 | c.1423A>T p.S475C | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.416); catalogued as COSV57760717; called by muse, mutect2, varscan2
- DNAJC27 | c.293T>A p.V98D | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV53095165; called by muse, mutect2, varscan2
- DNM2 | c.2377dup p.L793Pfs*31 (on ENST00000355667 / NM_001005360.3; = p.L789Pfs*31 on NM_004945.3) | Frame Shift Ins (INS) | VAF 24/76 reads (32%) | catalogued as rs764391392, COSV53034926; called by mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 40/70 reads (57%) | catalogued as rs782552436; called by mutect2, varscan2
- DOCK4 | c.2092A>G p.I698V | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV70237139; called by muse, mutect2, varscan2
- DOCK6 | c.4019G>A p.R1340H | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as rs558654486, COSV53915108; called by muse, mutect2, varscan2
- DOCK6 | c.3415G>A p.V1139M | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.526); catalogued as COSV53915127, COSV53920748; called by muse, mutect2, varscan2
- DOCK6 | c.901A>T p.N301Y | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52948998; called by muse, mutect2, varscan2
- DOCK7 | c.3427C>G p.P1143A (on ENST00000635253 / NM_001367561.1; = p.P1112A on NM_033407.3) | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.326); catalogued as COSV52006012, COSV99225267; called by muse, mutect2, varscan2
- DOK3 | c.107G>A p.G36D | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV57252384; called by muse, mutect2, varscan2
- DOP1A | c.5089T>C p.Y1697H | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.671); catalogued as rs1488901447, COSV52710497; called by muse, mutect2, varscan2
- DPEP2 | c.120dup p.R41Qfs*26 | Frame Shift Ins (INS) | VAF 10/40 reads (25%) | catalogued as rs547189498; called by mutect2, varscan2
- DPYSL2 | c.415G>A p.V139M | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.515); catalogued as COSV60783498; called by muse, mutect2, varscan2
- DQX1 | c.1489C>T p.L497F | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs200353206, COSV66353224; called by muse, mutect2, varscan2
- DQX1 | c.671T>G p.I224R | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV66353226; called by muse, mutect2, varscan2
- DSCAM | c.1601C>T p.S534F | Missense Mutation (SNP) | VAF 46/172 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV101258849; called by muse, mutect2, varscan2
- DSEL | c.896A>G p.Q299R | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1250205121, COSV100025143; called by muse, mutect2, varscan2
- DSEL | c.491G>A p.G164D | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.246); catalogued as COSV59491682; called by muse, mutect2, varscan2
- DSP | c.3584T>C p.V1195A | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.755); catalogued as COSV65792884; called by muse, mutect2, varscan2
- DST | c.17099A>G p.Y5700C (on ENST00000361203 / NM_001374722.1; = p.Y3397C on NM_015548.5) | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55015595; called by muse, mutect2, varscan2
- DTNB | c.721G>A p.V241M | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs1334452230, COSV56477013; called by muse, mutect2, varscan2
- DUOX2 | c.2810T>A p.F937Y | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV66532233; called by muse, mutect2, varscan2
- DUOX2 | c.893T>C p.V298A | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs527361236, COSV59908585; called by muse, mutect2, varscan2
- DUS1L | c.943_945del p.E315del | In Frame Del (DEL) | VAF 10/40 reads (25%) | catalogued as rs1334223753; called by pindel, varscan2
- DYNLT3 | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.739); catalogued as rs200218120, COSV66078926; called by muse, mutect2, varscan2
- DYRK4 | c.1465T>A p.S489T | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV50539529; called by muse, mutect2, varscan2
- E4F1 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs868100576, COSV57038338; called by muse, mutect2, varscan2
- ECRG4 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs368622171, COSV53000903; called by muse, mutect2, varscan2
- EHD3 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as rs775181095, COSV100434589; called by muse, mutect2, varscan2
- EHHADH | c.867G>T p.W289C | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV51630302; called by muse, mutect2, varscan2
- EIF2AK4 | c.3866A>C p.K1289T | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55468468; called by muse, mutect2, varscan2
- EIF3B | c.2081A>G p.N694S | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.038); catalogued as COSV100703507; called by muse, mutect2, varscan2
- EIF3L | c.1243T>C p.Y415H | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.744); catalogued as COSV67739636; called by muse, mutect2, varscan2
- EIF4E3 | c.373G>A p.V125I (on ENST00000425534 / NM_001134651.2; = p.V19I on NM_173359.5) | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.067); catalogued as rs770648457, COSV55204495; called by muse, mutect2, varscan2
- ELFN2 | c.439T>G p.F147V | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101297452; called by muse, mutect2
- ELL2 | c.1607T>C p.V536A | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.53); catalogued as COSV52982621; called by muse, mutect2, varscan2
- ELOA2 | c.1166A>T p.Y389F | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV55299440; called by muse, mutect2
- ELOA2 | c.104C>A p.S35Y | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99795733; called by muse, mutect2, varscan2
- EME1 | c.775+1G>A p.X259_splice | Splice Site (SNP) | VAF 7/32 reads (22%) | catalogued as COSV56812523; called by muse, mutect2, varscan2
- EML2 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55599733, COSV99840071; called by muse, mutect2, varscan2
- EML2 | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 5/16 reads (31%) | catalogued as rs201844947, COSV55599750, COSV55603473; called by muse, mutect2, varscan2
- EML5 | c.3154G>A p.G1052S | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61345815; called by muse, mutect2, varscan2
- EMSY | c.2848A>T p.K950* | Nonsense Mutation (SNP) | VAF 13/34 reads (38%) | catalogued as COSV58260519; called by muse, mutect2, varscan2
- ENDOU | c.763T>A p.S255T (on ENST00000422538 / NM_001172439.2; = p.S214T on NM_006025.4) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.449); catalogued as COSV57465071; called by muse, mutect2, varscan2
- ENTPD4 | c.178C>T p.R60* | Nonsense Mutation (SNP) | VAF 12/55 reads (22%) | catalogued as rs372620648; called by muse, mutect2, varscan2
- ENTR1 | c.595G>A p.E199K (on ENST00000357365 / NM_001039707.2; = p.E176K on NM_006643.4) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.08); catalogued as rs528599672, COSV53741591; called by muse, mutect2, varscan2
- EPHB6 | c.2805-1G>T p.X935_splice | Splice Site (SNP) | VAF 9/33 reads (27%) | catalogued as COSV63891850; called by muse, mutect2, varscan2
- EPPK1 | c.4258C>T p.R1420C | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as rs376120694; called by muse, varscan2
- EPPK1 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs927778676, COSV101599983, COSV73261333; called by muse, mutect2
- EPS15 | c.2394T>A p.D798E | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.057); catalogued as COSV65542454; called by muse, mutect2, varscan2
- EPX | c.786dup p.C263Lfs*10 | Frame Shift Ins (INS) | VAF 4/18 reads (22%) | catalogued as rs1409507270; called by mutect2, pindel, varscan2
- ERBB4 | c.1744C>T p.H582Y | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.291); catalogued as rs1559395766, COSV53533809; called by muse, mutect2, varscan2
- ERC2 | c.960A>T p.K320N | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.093); catalogued as COSV55623216; called by muse, mutect2, varscan2
- ERCC6 | c.2299C>T p.R767C | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs370105701; called by muse, mutect2
- ERCC6L | c.2066A>T p.D689V | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV57820736; called by muse, mutect2, varscan2
- ERCC6L2 | c.1925A>G p.Y642C | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56630492; called by muse, mutect2, varscan2
- ERLEC1 | c.1124C>A p.S375Y | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); catalogued as COSV51751860, COSV99483341; called by muse, mutect2, varscan2
- ERN2 | c.2221C>G p.L741V | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV99890397; called by muse, mutect2
- ESR2 | c.589C>T p.R197W | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760053106, CM142389, COSV50831269, COSV99963815; called by muse, mutect2, varscan2
- ESRRG | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); catalogued as COSV63161279, COSV63161430; called by muse, mutect2, varscan2
- ETNPPL | c.362G>T p.R121L | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV56595896; called by muse, mutect2, varscan2
- ETV6 | c.550T>A p.S184T | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.643); catalogued as COSV67150248; called by muse, mutect2, varscan2
- ETV6 | c.1123G>A p.G375R | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56765416, COSV56766903, COSV56766981; called by muse, mutect2, varscan2
- EVC | c.2024G>A p.R675Q | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs143728868, COSV53840319, COSV99380963; called by muse, mutect2, varscan2
- EXOC3L2 | c.1492C>T p.R498* | Nonsense Mutation (SNP) | VAF 13/39 reads (33%) | catalogued as COSV52973064; called by muse, mutect2, varscan2
- EXOC3L4 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1266475868, COSV66295890; called by muse, mutect2
- EXOC4 | c.1550G>C p.G517A | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV54098974; called by muse, mutect2, varscan2
- EXOC8 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.445); catalogued as COSV50478277; called by muse, mutect2, varscan2
- F8 | c.6616G>A p.D2206N | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.399); catalogued as COSV57705233; called by muse, mutect2, varscan2
- FAM160A2 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.15); catalogued as COSV99791625; called by muse, mutect2, varscan2
- FAM167A | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.104); catalogued as rs370162158; called by muse, mutect2, varscan2
- FAM189B | c.223T>A p.S75T | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as COSV56945217; called by muse, mutect2, varscan2
- FAM193A | c.2315A>G p.E772G | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61194275; called by muse, mutect2, varscan2
- FAM47C | c.1099C>T p.R367C | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs1556332120, COSV100792984, COSV63726021; called by muse, mutect2, varscan2
- FAM98A | c.515A>G p.E172G | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV53209344, COSV53210292; called by muse, mutect2, varscan2
- FANCC | c.1337T>A p.V446E | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.601); catalogued as COSV56660697; called by muse, mutect2
- FASN | c.4156C>A p.L1386M | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV60755016; called by muse, mutect2, varscan2
- FASN | c.1150C>T p.R384C | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.61); catalogued as rs762823912, COSV60752905; called by muse, mutect2, varscan2
- FAT2 | c.11156G>A p.R3719Q | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.084); catalogued as rs1344751631, COSV55820109; called by muse, mutect2, varscan2
- FAT3 | c.5228C>T p.A1743V | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53112674, COSV99966803; called by muse, mutect2, varscan2
- FAT4 | c.7777G>T p.G2593* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as COSV100627032; called by muse, mutect2
- FAT4 | c.13617del p.E4541Rfs*31 | Frame Shift Del (DEL) | VAF 7/67 reads (10%) | catalogued as COSV58700327; called by mutect2, pindel, varscan2
- FBLN2 | c.2624G>A p.C875Y | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55484808; called by muse, mutect2, varscan2
- FBLN2 | c.2807C>T p.A936V | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.616); catalogued as rs199603685; called by muse, mutect2, varscan2
- FBN1 | c.2115G>A p.A705= | Splice Region (SNP) | VAF 14/54 reads (26%) | catalogued as rs932764622, COSV57317234; ClinVar: likely benign; called by muse, mutect2, varscan2
- FBXL16 | c.959C>G p.P320R | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100178657, COSV100178747; called by mutect2, varscan2
- FBXO11 | c.659A>G p.Q220R (on ENST00000403359 / NM_001190274.2; = p.Q136R on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs367772526; called by muse, mutect2, varscan2
- FBXW10 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100111157; called by muse, mutect2, varscan2
- FCAMR | c.595G>A p.G199S | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs559768863, COSV61367774; called by muse, mutect2, varscan2
- FCGBP | c.11642C>T p.A3881V | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.035); catalogued as rs201350567; called by muse, mutect2, varscan2
- FCGBP | c.11236G>A p.A3746T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.254); catalogued as rs368867080; called by muse, mutect2, varscan2
- FCN3 | c.383dup p.G129Rfs*32 | Frame Shift Ins (INS) | VAF 23/100 reads (23%) | catalogued as rs750716179; called by mutect2, pindel, varscan2
- FER1L5 | c.4232A>C p.E1411A (on ENST00000623019; = p.E1384A on NM_001293083.2) | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.115); catalogued as COSV67606225; called by muse, mutect2, varscan2
- FGA | c.2386G>A p.E796K | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV57396256; called by muse, mutect2, varscan2
- FGF2 | c.770A>T p.Y257F | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.494); catalogued as COSV52650020; called by muse, mutect2, varscan2
- FGF23 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs200445443, COSV52975670; called by muse, mutect2, varscan2
- FH | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV100844967; called by muse, mutect2
- FLAD1 | c.47G>T p.R16M | Missense Mutation (SNP) | VAF 13/31 reads (42%) | PolyPhen benign (0.133); catalogued as COSV52697126; called by muse, mutect2, varscan2
- FLG | c.2081C>T p.A694V | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs748903619, COSV100910357; called by muse, mutect2, varscan2
- FLNC | c.4275dup p.R1426Afs*85 | Frame Shift Ins (INS) | VAF 5/24 reads (21%) | catalogued as rs756985550; called by mutect2, pindel, varscan2
- FLNC | c.6121G>A p.A2041T | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs745842738, COSV57950890; called by muse, mutect2, varscan2
- FMR1 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV54424041; called by muse, mutect2, varscan2
- FNBP4 | c.2061G>A p.M687I | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99771358; called by muse, mutect2, varscan2
- FNDC5 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs369474610; called by muse, mutect2, varscan2
- FNDC7 | c.1184T>C p.V395A | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV99600830; called by muse, mutect2, varscan2
- FOXB2 | c.788C>T p.T263M | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.353); catalogued as COSV100942274; called by muse, mutect2
- FOXD3 | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64379981; called by muse, varscan2
- FOXG1 | c.115C>T p.H39Y | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as COSV100486494; called by muse, varscan2
- FOXG1 | c.1419T>G p.D473E | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV100486495; called by muse, mutect2, varscan2
- FOXN4 | c.943C>T p.R315W | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs762307757, COSV100142015; called by muse, mutect2, varscan2
- FOXO3 | c.790C>A p.R264S | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV59628313; called by muse, mutect2, varscan2
- FOXO4 | c.167A>G p.E56G | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1205070460; called by muse, mutect2
- FRMD4A | c.2770G>A p.V924I | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); catalogued as rs779709485, COSV62264208; called by muse, mutect2
- FRMD4A | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV52723625; called by muse, mutect2, varscan2
- FTMT | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as COSV58420388, COSV58421141; called by muse, mutect2, varscan2
- FTSJ3 | c.2164_2166del p.K722del | In Frame Del (DEL) | VAF 27/146 reads (18%) | catalogued as rs769328765; called by pindel, varscan2
- FUBP3 | c.740T>A p.F247Y | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.79); PolyPhen benign (0.323); catalogued as COSV60514281; called by muse, mutect2, varscan2
- FUBP3 | c.1621C>T p.P541S | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as COSV60514290; called by muse, mutect2
- FUT1 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59568341; called by muse, mutect2, varscan2
- FUT2 | c.353C>T p.T118M | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.179); catalogued as rs760999180, COSV67179338; called by muse, mutect2, varscan2
- FZD10 | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57473653; called by muse, mutect2, varscan2
- FZD3 | c.888dup p.T297Yfs*25 | Frame Shift Ins (INS) | VAF 50/83 reads (60%) | catalogued as rs765036679; called by mutect2, varscan2
- GABPA | c.22G>T p.E8* | Nonsense Mutation (SNP) | VAF 53/257 reads (21%) | catalogued as COSV61396308; called by muse, mutect2, varscan2
- GABRA5 | c.796C>A p.L266I | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (1); PolyPhen possibly damaging (0.856); catalogued as COSV100164667; called by muse, varscan2
- GABRB3 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54665043; called by muse, mutect2, varscan2
- GABRD | c.257C>T p.T86I | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66080653; called by muse, mutect2, varscan2
- GALNT13 | c.1276C>T p.R426C | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as rs150203694; called by muse, mutect2, varscan2
- GALNT17 | c.1750C>T p.R584C | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs774608303, COSV61148013; called by muse, mutect2, varscan2
- GANC | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 25/95 reads (26%) | PolyPhen probably damaging (1); catalogued as rs368575859; called by muse, mutect2, varscan2
- GAPDHS | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.64); catalogued as rs750502242, COSV55880079; called by muse, mutect2, varscan2
- GATA3 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs201023943, COSV60518691, COSV60521826; called by muse, mutect2, varscan2
- GDAP2 | c.918A>T p.L306F | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.165); catalogued as COSV65612528; called by muse, mutect2, varscan2
- GDF9 | c.614T>A p.F205Y | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.84); PolyPhen benign (0.176); catalogued as COSV51526368; called by muse, mutect2, varscan2
- GEM | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1301234891, COSV52597439; called by muse, mutect2, varscan2
- GEMIN4 | c.2429G>A p.G810E | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56745617; called by mutect2, varscan2
- GEMIN7 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV54319703; called by muse, mutect2, varscan2
- GGCX | c.2026C>T p.P676S | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV52088394; called by muse, mutect2, varscan2
- GGCX | c.332C>A p.P111Q | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV52088407; called by muse, mutect2, varscan2
- GIGYF2 | c.3262C>G p.P1088A | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.591); catalogued as COSV65249611; called by muse, mutect2, varscan2
- GIMAP1 | c.898G>A p.V300I | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.005); catalogued as rs752300708, COSV56188181; called by muse, mutect2, varscan2
- GJA4 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs774261822, COSV60724746; called by muse, mutect2, varscan2
- GJA5 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs782301284, COSV54784288; called by muse, mutect2, varscan2
- GLCE | c.1112A>G p.K371R | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as COSV99962028; called by muse, mutect2, varscan2
- GLDC | c.1891G>T p.A631S | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.114); catalogued as COSV100394574, COSV58680253; called by muse, mutect2, varscan2
- GLI3 | c.2941G>A p.D981N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); catalogued as rs746678996, COSV67891420; called by muse, mutect2, varscan2
- GLRX3 | c.464A>C p.Q155P | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.334); catalogued as rs1023501686, COSV100487830; called by muse, mutect2, varscan2
- GLT8D1 | c.496_498del p.K166del | In Frame Del (DEL) | VAF 19/92 reads (21%) | catalogued as rs752673790; called by pindel, varscan2
- GLUD2 | c.405C>A p.Y135* | Nonsense Mutation (SNP) | VAF 21/40 reads (53%) | catalogued as COSV60151993; called by muse, mutect2, varscan2
- GNAI2 | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99806764; called by muse, mutect2, varscan2
- GPATCH2L | c.1205T>C p.V402A | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV99833305; called by muse, mutect2, varscan2
- GPBAR1 | c.535G>T p.G179C | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV50307741; called by muse, mutect2, varscan2
- GPR158 | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747936646, COSV66270630; called by muse, mutect2, varscan2
- GPR45 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.823); catalogued as rs369449960; called by muse, mutect2, varscan2
- GPR78 | c.689T>C p.I230T | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0.012); catalogued as COSV66763119; called by muse, mutect2, varscan2
- GRID1 | c.1375C>A p.Q459K | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as COSV60029440; called by muse, mutect2, varscan2
- GRIK2 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs577245133, COSV59713577, COSV59737795; called by muse, mutect2, varscan2
- GRIN2D | c.2410G>A p.D804N | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); catalogued as COSV53521093; called by muse, mutect2
- GRM3 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV64467252; called by muse, mutect2, varscan2
- GSX2 | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as COSV58842462; called by muse, mutect2, varscan2
- GTF2IRD1 | c.1043T>A p.I348N | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56086796, COSV99735914; called by muse, mutect2, varscan2
- GUCY1B1 | c.1220G>A p.R407Q | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.64); catalogued as COSV52375767; called by muse, mutect2, varscan2
- H2AC20 | c.58T>C p.S20P | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.98); catalogued as rs1553759870, COSV58612030; called by muse, mutect2, varscan2
- H3C6 | c.134G>C p.G45A | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.043); catalogued as COSV64519605; called by muse, mutect2, varscan2
- HARS1 | c.172A>C p.T58P | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV100047476; called by mutect2, varscan2
- HAUS5 | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.942); catalogued as rs748280739, COSV52547999; called by muse, mutect2, varscan2
- HDAC9 | c.22G>T p.V8L | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV67773576; called by muse, mutect2, varscan2
- HECTD3 | c.1780G>A p.D594N | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); catalogued as COSV64670199; called by muse, mutect2, varscan2
- HECW2 | c.3398C>T p.A1133V | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.703); catalogued as COSV53660126; called by muse, mutect2, varscan2
- HERC1 | c.13204C>T p.R4402W | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs777743186, COSV71247893; called by muse, mutect2, varscan2
- HINT3 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV57649873; called by muse, mutect2, varscan2
- HIP1R | c.160A>T p.I54F | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53441716; called by muse, mutect2, varscan2
- HMCES | c.26T>A p.L9* | Nonsense Mutation (SNP) | VAF 11/50 reads (22%) | catalogued as COSV59114203; called by muse, mutect2, varscan2
- HMCN1 | c.2818C>T p.R940C | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768946010, COSV54901712; called by muse, mutect2, varscan2
- HORMAD1 | c.268C>T p.Q90* | Nonsense Mutation (SNP) | VAF 51/177 reads (29%) | catalogued as COSV59271204; called by muse, mutect2, varscan2
- HPS5 | c.913A>T p.T305S (on ENST00000349215 / NM_181507.2; = p.T191S on NM_007216.4) | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.787); catalogued as COSV61687525; called by muse, mutect2, varscan2
- HROB | c.1519C>T p.R507W | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs373059575; called by muse, mutect2, varscan2
- HSP90B1 | c.599A>T p.Y200F | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55355461; called by muse, mutect2, varscan2
- HTR4 | c.299A>G p.D100G | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58795403; called by muse, mutect2, varscan2
- HTR6 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs200329647, COSV57033044; called by muse, mutect2, varscan2
- HTR7 | c.1012G>A p.V338M | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as rs141895642; called by muse, mutect2, varscan2
- HUWE1 | c.11251G>T p.G3751C | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.766); catalogued as COSV53346190; called by muse, mutect2, varscan2
- ICE2 | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs748464020, COSV55031532; called by muse, mutect2, varscan2
- IDH3B | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs764236244, COSV61390071; called by muse, mutect2, varscan2
- IDO1 | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53714172; called by muse, mutect2, varscan2
- IFFO1 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV59110677; called by muse, mutect2, varscan2
- IFIT3 | c.95G>T p.R32M | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.06); catalogued as COSV99259653; called by muse, mutect2, varscan2
- IFT172 | c.833C>G p.A278G | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.02); catalogued as COSV53133918; called by muse, mutect2, varscan2
- IFT46 | c.571C>T p.R191C (on ENST00000264021 / NM_001168618.2; = p.R242C on NM_020153.3) | Missense Mutation (SNP) | VAF 48/173 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs782595984, COSV50594348; called by muse, mutect2, varscan2
- IGF1 | c.451G>T p.G151C (on ENST00000307046 / NM_001111285.3; = p.G151* on NM_001111283.3) | Missense Mutation (SNP) | VAF 72/262 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); catalogued as COSV61031904, COSV61032633; called by muse, varscan2
- IGF1R | c.3433G>A p.E1145K | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as rs769418210, COSV51289356; called by muse, mutect2, varscan2
- IGF2R | c.3264C>T p.D1088= | Splice Region (SNP) | VAF 12/142 reads (8%) | catalogued as COSV63629303; called by muse, mutect2
- IGFL3 | c.143A>G p.Y48C | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV58242800; called by muse, mutect2, varscan2
- IKZF2 | c.696G>T p.Q232H | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.305); catalogued as COSV59578761, COSV59579917; called by muse, mutect2, varscan2
- IL16 | c.1364C>T p.A455V | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV57263755; called by muse, mutect2, varscan2
- IL21R | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV61970518; called by muse, mutect2, varscan2
- IL22RA1 | c.461T>A p.L154Q | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.108); catalogued as rs764086403, COSV54628758; called by muse, mutect2
- IL4I1 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.094); catalogued as rs369942631, COSV62010046; called by muse, mutect2, varscan2
- IL6R | c.596G>A p.G199E | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59816663; called by muse, mutect2, varscan2
- ILF3 | c.1004G>A p.G335D | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51557869; called by muse, mutect2, varscan2
- ILK | c.211del p.L71Cfs*26 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | catalogued as rs776120061, COSV54448886; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- INA | c.1037G>A p.R346Q | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs868129569, COSV63975988; called by muse, mutect2, varscan2
- ING3 | c.706A>G p.T236A | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV59951035; called by muse, mutect2, varscan2
- INSRR | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.061); catalogued as COSV63873256; called by muse, mutect2, varscan2
- INTS2 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0.084); catalogued as COSV99247637; called by muse, mutect2, varscan2
- INTS7 | c.2380T>A p.Y794N | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65344330; called by muse, mutect2, varscan2
- INTS7 | c.1040T>A p.L347* | Nonsense Mutation (SNP) | VAF 30/120 reads (25%) | catalogued as COSV65344304, COSV65344335; called by muse, mutect2, varscan2
- IQSEC3 | c.1571C>T p.A524V (on ENST00000538872 / NM_001170738.2; = p.A221V on NM_015232.1) | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs782495678, COSV100406742; called by muse, mutect2
- IRAG1 | c.2077C>T p.R693C | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs893679901, COSV101351177, COSV70210967; called by muse, mutect2, varscan2
- IRF7 | c.1398G>A p.L466= (on ENST00000397566; = p.L453= on NM_001572.5) | Splice Region (SNP) | VAF 9/18 reads (50%) | catalogued as COSV52756077; called by muse, mutect2, varscan2
- IRF8 | c.917G>A p.C306Y | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51898117; called by muse, mutect2, varscan2
- ISG20L2 | c.865dup p.L289Pfs*6 | Frame Shift Ins (INS) | VAF 16/59 reads (27%) | catalogued as rs761558950; called by mutect2, varscan2
- ISLR2 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62302206; called by muse, mutect2, varscan2
- ISOC1 | c.886T>C p.S296P | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99434319; called by muse, mutect2
- IST1 | c.587T>A p.V196D (on ENST00000535424 / NM_001270976.1; = p.V183D on NM_014761.4) | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV61709730; called by muse, mutect2, varscan2
- ITGA2B | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1484422253, COSV52232648; called by muse, mutect2, varscan2
- ITGB1 | c.2006A>T p.N669I | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.548); catalogued as COSV56481794; called by muse, mutect2
- ITGBL1 | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 43/172 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as rs749949431, COSV66008250; called by muse, mutect2, varscan2
- ITIH6 | c.1741G>A p.D581N | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as COSV54489285; called by muse, mutect2, varscan2
- ITPR1 | c.7763T>C p.V2588A (on ENST00000354582; = p.V2533A on NM_002222.7) | Missense Mutation (SNP) | VAF 58/180 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56982446; called by muse, mutect2, varscan2
- ITSN1 | c.1996C>T p.Q666* | Nonsense Mutation (SNP) | VAF 20/55 reads (36%) | catalogued as COSV66083250; called by muse, mutect2, varscan2
- IVNS1ABP | c.1489C>T p.P497S | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.011); catalogued as COSV62251116; called by muse, mutect2, varscan2
- JAG2 | c.462T>A p.D154E | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV59309182; called by muse, mutect2, varscan2
- JAK1 | c.1345G>A p.A449T | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs765489448, COSV61088810; called by muse, mutect2, varscan2
- JAKMIP2 | c.939A>G p.L313= | Splice Region (SNP) | VAF 19/78 reads (24%) | catalogued as COSV54604994; called by muse, mutect2, varscan2
- JAKMIP3 | c.1101G>T p.Q367H | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV53823413; called by muse, mutect2, varscan2
- JPH4 | c.1702G>A p.A568T | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs374606285; called by muse, mutect2, varscan2
- JUP | c.866C>T p.T289I | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV100159277; called by muse, mutect2, varscan2
- KATNIP | c.809-1G>T p.X270_splice | Splice Site (SNP) | VAF 10/33 reads (30%) | catalogued as COSV55180974; called by muse, mutect2, varscan2
- KBTBD6 | c.251G>A p.C84Y | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65271308; called by muse, mutect2, varscan2
- KCNA3 | c.383C>T p.T128M | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63901232; called by muse, mutect2, varscan2
- KCNA4 | c.1286del p.G429Vfs*53 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs1258313537; called by mutect2, pindel, varscan2
- KCNH1 | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55082332; called by muse, varscan2
- KCNJ16 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142348698; called by muse, mutect2, varscan2
- KCNK16 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1399673497, COSV100949043; called by muse, mutect2, varscan2
- KCNK17 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs747130965, COSV64685589; called by muse, mutect2, varscan2
- KCNK9 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); catalogued as rs1222560554, COSV100270171; called by muse, mutect2, varscan2
- KCNQ1 | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.621); catalogued as rs775362401, COSV99325451; ClinVar: uncertain significance; called by muse, mutect2
- KCTD11 | c.602G>A p.R201H (on ENST00000333751 / NM_001363642.1; = p.R162H on NM_001002914.2) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as rs865964999, COSV50134200; called by muse, mutect2, varscan2
- KDM3B | c.3911T>A p.L1304H | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58690852; called by muse, mutect2, varscan2
- KDM4A | c.2206G>A p.V736I | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs757083813, COSV100969346; called by muse, mutect2, varscan2
- KDR | c.43G>A p.V15M | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1023303395, COSV55765572; called by muse, mutect2, varscan2
- KHNYN | c.1577+1G>A p.X526_splice | Splice Site (SNP) | VAF 5/60 reads (8%) | catalogued as COSV52158510; called by muse, mutect2
- KIAA1109 | c.2981G>A p.R994H | Missense Mutation (SNP) | VAF 70/261 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1361061057, COSV52674179; called by muse, mutect2, varscan2
- KIAA1522 | c.1550G>A p.R517Q (on ENST00000373480 / NM_001198972.2; = p.R576Q on NM_020888.3) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746211710, COSV53863448; called by muse, mutect2
- KIAA1549 | c.4681C>T p.R1561* | Nonsense Mutation (SNP) | VAF 11/54 reads (20%) | catalogued as rs765542806, COSV54314610; called by muse, mutect2, varscan2
- KIAA1755 | c.2113G>A p.A705T | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as rs746025973, COSV54076680; called by muse, mutect2, varscan2
- KIAA1841 | c.1345G>C p.D449H | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54375060; called by muse, mutect2, varscan2
- KIDINS220 | c.3899C>T p.P1300L | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.009); catalogued as rs372587282; called by muse, mutect2, varscan2
- KIF18A | c.2003G>A p.R668Q | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.401); catalogued as rs372157089; called by muse, mutect2, varscan2
- KIF2C | c.1747G>A p.D583N | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.524); catalogued as COSV64764546; called by muse, mutect2, varscan2
- KIF3C | c.1613T>C p.M538T | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.054); catalogued as COSV99266950; called by muse, mutect2, varscan2
- KIF3C | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.49); catalogued as rs747801679, COSV53098969; called by muse, mutect2, varscan2
- KIF6 | c.1256G>A p.R419H | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs780284536, COSV54677726; called by muse, mutect2, varscan2
- KL | c.1780C>T p.R594C | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs138511256; ClinVar: uncertain significance; called by muse, mutect2
- KLF3 | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as COSV54710504; called by muse, mutect2, varscan2
- KLHL14 | c.1543G>A p.V515I | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as rs781612051, COSV63832564; called by muse, mutect2, varscan2
- KLHL14 | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.989); catalogued as rs1298586737, COSV63832569; called by muse, mutect2, varscan2
- KLHL21 | c.1633C>T p.R545W | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs760923196, COSV66553552; called by muse, mutect2, varscan2
- KLK11 | c.199T>C p.W67R (on ENST00000594768 / NM_144947.3; = p.W35R on NM_006853.3) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51577194; called by muse, mutect2, varscan2
- KNTC1 | c.566G>A p.G189E | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.82); catalogued as COSV100337844; called by muse, mutect2, varscan2
- KPNA6 | c.964G>A p.V322I | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs1200353435, COSV65360171; called by muse, mutect2, varscan2
- KREMEN1 | c.494A>G p.Y165C (on ENST00000407188; = p.Y167C on NM_032045.5) | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as rs774077658, COSV100588536; called by muse, mutect2, varscan2
- KRT10 | c.608T>C p.I203T | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV54089786; called by muse, mutect2, varscan2
- KRT5 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.197); catalogued as rs543574061, COSV52860790; called by muse, mutect2, varscan2
- KRTAP10-2 | c.518G>A p.C173Y | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV59962994; called by muse, mutect2, varscan2
- KRTAP5-7 | c.257dup p.C87Lfs*13 | Frame Shift Ins (INS) | VAF 24/114 reads (21%) | catalogued as rs779930672; called by mutect2, pindel, varscan2
- KTN1 | c.70T>A p.F24I | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68023608; called by muse, mutect2, varscan2
- KTN1 | c.71T>A p.F24Y | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68023614; called by muse, mutect2, varscan2
- L1CAM | c.3616G>A p.D1206N | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100648821; called by muse, mutect2, varscan2
- LAMA1 | c.5347C>T p.L1783F | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs369357307; called by muse, mutect2, varscan2
- LAMA2 | c.7913A>G p.Q2638R | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV70347605; called by muse, mutect2, varscan2
- LAMA4 | c.1616A>T p.D539V (on ENST00000230538 / NM_001105206.3; = p.D532V on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV57897438; called by muse, mutect2, varscan2
- LAMA5 | c.3217C>T p.R1073W | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs1256118723, COSV99442226; called by muse, mutect2
- LAMP1 | c.967G>A p.G323S | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs371034089; called by muse, mutect2, varscan2
- LAMP3 | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 172/564 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.231); catalogued as COSV55614950; called by muse, mutect2, varscan2
- LARP1 | c.2962T>C p.Y988H (on ENST00000518297 / NM_033551.3; = p.Y911H on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60427199; called by muse, mutect2, varscan2
- LARP7 | c.246dup p.L83Ifs*4 | Frame Shift Ins (INS) | VAF 57/224 reads (25%) | catalogued as rs1318486735; called by mutect2, pindel, varscan2
- LARS1 | c.1064A>G p.E355G (on ENST00000394434 / NM_020117.11; = p.E328G on NM_016460.3) | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV50976565; called by muse, mutect2, varscan2
- LCN12 | c.555G>A p.W185* | Nonsense Mutation (SNP) | VAF 11/41 reads (27%) | catalogued as COSV65421782; called by muse, mutect2, varscan2
- LEMD1 | c.361G>A p.A121T (on ENST00000367151; = p.E73= on NM_001001552.5) | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.025); catalogued as COSV65671548; called by muse, mutect2, varscan2
- LEO1 | c.407A>G p.E136G | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV55175854; called by muse, mutect2, varscan2
- LEO1 | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 47/152 reads (31%) | catalogued as COSV55175866; called by muse, mutect2, varscan2
- LEXM | c.821A>G p.H274R | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV64022716; called by muse, mutect2, varscan2
- LGR5 | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as rs565985845, COSV57005211; called by muse, mutect2, varscan2
- LGR6 | c.1853T>C p.L618P (on ENST00000367278 / NM_001017403.1; = p.L566P on NM_021636.3) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761460371, COSV55157660; called by muse, mutect2, varscan2
- LHX1 | c.1194dup p.E399Rfs*65 | Frame Shift Ins (INS) | VAF 8/35 reads (23%) | catalogued as rs775423572; called by mutect2, varscan2
- LIMK1 | c.1505A>G p.D502G | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.143); catalogued as COSV100282938; called by muse, mutect2, varscan2
- LIMK1 | c.1750G>A p.V584M | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.456); catalogued as rs782109144, COSV60280928; called by muse, mutect2, varscan2
- LIMS2 | c.634G>A p.A212T (on ENST00000355119 / NM_001161403.3; = p.A236T on NM_017980.4) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs762554883, COSV55755307; called by muse, mutect2, varscan2
- LIPG | c.1284G>T p.K428N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as COSV54297373, COSV99724229; called by mutect2, varscan2
- LOXL2 | c.1903T>A p.F635I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101207702, COSV66692644; called by muse, mutect2, varscan2
- LPCAT1 | c.725T>G p.L242R | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV99358664; called by muse, mutect2, varscan2
- LRFN2 | c.1594G>A p.G532S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1485565179, COSV57824137, COSV57831955; called by muse, mutect2, varscan2
- LRFN2 | c.382C>T p.H128Y | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100599041; called by muse, mutect2, varscan2
- LRFN4 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1339607139, COSV58921657; called by muse, mutect2, varscan2
- LRP12 | c.2122G>T p.G708* | Nonsense Mutation (SNP) | VAF 19/59 reads (32%) | catalogued as COSV52628986; called by muse, mutect2, varscan2
- LRP2 | c.12691C>T p.P4231S | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99786131; called by muse, mutect2, varscan2
- LRP2 | c.5491A>T p.I1831F | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV55554040; called by muse, mutect2, varscan2
- LRP6 | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs752144608, COSV53786607; called by muse, mutect2, varscan2
- LRRC31 | c.10A>T p.T4S | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.026); catalogued as COSV52981068; called by muse, mutect2, varscan2
- LRRC47 | c.473T>A p.L158H | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV65562527; called by muse, mutect2, varscan2
- LRRC4C | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); catalogued as rs375080235, COSV99539146; called by muse, varscan2
- LRRC75B | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.134); catalogued as COSV50640563; called by muse, mutect2, varscan2
- LRRK1 | c.5009G>A p.C1670Y | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52612296; called by muse, mutect2, varscan2
- LRRN1 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs561448571, COSV60015303; called by muse, varscan2
- LRWD1 | c.1229C>T p.T410M | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760721958, COSV52960492; called by muse, mutect2, varscan2
- LSM4 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.055); catalogued as COSV53253670; called by muse, mutect2, varscan2
- LTBP1 | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63187398; called by muse, mutect2, varscan2
- LUC7L2 | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.964); catalogued as rs761427902, COSV54926266; called by mutect2, varscan2
- LYAR | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58642899; called by muse, mutect2, varscan2
- LYST | c.9989C>T p.A3330V | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101087856; called by muse, mutect2
- LYST | c.9461G>A p.G3154D | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67707166; called by muse, mutect2, varscan2
- MACF1 | c.3499C>G p.Q1167E | Missense Mutation (SNP) | VAF 18/60 reads (30%) | catalogued as COSV58368681, COSV58374445; called by muse, mutect2, varscan2
- MACF1 | c.15401G>A p.R5134Q (on ENST00000372915; = p.R3067Q on NM_012090.5) | Missense Mutation (SNP) | VAF 21/82 reads (26%) | catalogued as rs199851077, COSV57121985; called by muse, mutect2, varscan2
- MAEA | c.135C>G p.S45R | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.449); catalogued as COSV53262617; called by muse, mutect2, varscan2
- MAF | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV58154208; called by muse, mutect2, varscan2
- MAGEA11 | c.154C>A p.P52T | Missense Mutation (SNP) | VAF 39/69 reads (57%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.043); catalogued as COSV60755652; called by muse, mutect2, varscan2
- MAGI2 | c.3013C>T p.R1005C | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs1286180540, COSV62661068; called by muse, mutect2, varscan2
- MAML3 | c.2677A>G p.T893A | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV72209126; called by muse, mutect2, varscan2
- MAN1A1 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.293); catalogued as COSV63782648, COSV63784126; called by muse, mutect2, varscan2
- MAN2C1 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as rs199696370, COSV51229251; called by muse, mutect2, varscan2
- MAP1A | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV55809007; called by muse, mutect2, varscan2
- MAP3K10 | c.599C>A p.A200D | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99453841; called by muse, mutect2, varscan2
- MAP3K14 | c.2081C>T p.S694L | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs755630489, COSV60923752; called by mutect2, varscan2
- MAPK1IP1L | c.418G>C p.G140R | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV67106446; called by muse, mutect2, varscan2
- MAPK4 | c.1397C>T p.A466V | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.006); catalogued as rs1443679870, COSV68542688, COSV68543167; called by muse, mutect2, varscan2
- MAPK8IP1 | c.1277C>T p.A426V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.164); catalogued as rs1437718746, COSV53797896; called by muse, mutect2
- MARF1 | c.4867G>A p.D1623N | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV60023856; called by muse, mutect2, varscan2
- MARF1 | c.166A>T p.K56* | Nonsense Mutation (SNP) | VAF 26/86 reads (30%) | catalogued as COSV60023872; called by muse, mutect2, varscan2
- MAST3 | c.2525G>A p.R842H | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.839); catalogued as rs761058921, COSV53220779; called by muse, mutect2, varscan2
- MAX | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 70/206 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.838); catalogued as COSV99408317; called by muse, mutect2, varscan2
- MBD5 | c.1423C>T p.P475S | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.201); catalogued as rs1323127834, COSV68697107; called by muse, mutect2, varscan2
- MBD6 | c.2458T>C p.S820P | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.003); catalogued as COSV63076271; called by muse, mutect2, varscan2
- MCHR2 | c.290del p.G97Efs*28 | Frame Shift Del (DEL) | VAF 13/62 reads (21%) | catalogued as COSV56007053; called by mutect2, pindel, varscan2
- MCM7 | c.2119T>C p.W707R | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV100384507; called by muse, mutect2, varscan2
- MCOLN1 | c.1615G>A p.A539T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs758163053, COSV51178149; called by mutect2, varscan2
- MDN1 | c.10189G>A p.V3397M | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs769872893, COSV65517753; called by muse, mutect2, varscan2
- MED12L | c.1580C>T p.A527V | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1195134783, COSV56379534; called by muse, mutect2, varscan2
- MED13 | c.6208T>G p.S2070A | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV67263623; called by muse, mutect2, varscan2
- MED13L | c.2566C>G p.P856A | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.168); catalogued as COSV56120350; called by muse, mutect2, varscan2
- MEGF6 | c.4318dup p.A1440Gfs*4 | Frame Shift Ins (INS) | VAF 20/76 reads (26%) | catalogued as rs759225724; called by mutect2, varscan2
- MEGF8 | c.4883G>A p.R1628H (on ENST00000251268 / NM_001271938.2; = p.R1561H on NM_001410.3) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1446634762, COSV52085499; called by muse, mutect2
- MEOX2 | c.490G>A p.G164S | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs141784602; called by muse, mutect2, varscan2
- METTL21A | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.289); catalogued as rs372280518, COSV55881587; called by muse, mutect2, varscan2
- METTL25 | c.1405-1G>A p.X469_splice | Splice Site (SNP) | VAF 5/32 reads (16%) | catalogued as COSV50259173; called by muse, mutect2, varscan2
- MEX3B | c.1082C>A p.P361H | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV100313818; called by muse, varscan2
- MEX3B | c.1037del p.G346Efs*181 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | catalogued as rs1406688622; called by pindel, varscan2
- MFN1 | c.660del p.H221Tfs*3 | Frame Shift Del (DEL) | VAF 17/68 reads (25%) | catalogued as COSV54940877; called by mutect2, pindel, varscan2
- MGA | c.1832C>A p.P611H | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV54954186; called by muse, mutect2, varscan2
- MGAM | c.3587C>T p.T1196M | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs756381544, COSV101527347; called by muse, mutect2, varscan2
- MGARP | c.81C>T p.D27= | Splice Region (SNP) | VAF 4/26 reads (15%) | catalogued as rs748089511, COSV67449365; called by mutect2, varscan2
- MIA3 | c.5351G>A p.R1784Q | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.743); catalogued as rs950931387, COSV60518760; called by muse, mutect2, varscan2
- MICAL1 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.523); catalogued as rs572866945, COSV62193644; called by muse, mutect2
- MID1 | c.1616G>A p.G539D | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58194688; called by muse, mutect2, varscan2
- MIGA1 | c.1851T>A p.S617R | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as COSV66223708; called by muse, mutect2, varscan2
- MIOS | c.2075G>A p.R692K | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.729); catalogued as COSV60768503; called by muse, mutect2, varscan2
- MKRN1 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as COSV55436792; called by muse, mutect2, varscan2
- MKX | c.907A>G p.T303A | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.696); catalogued as rs1455099579, COSV65392225; called by muse, mutect2, varscan2
- MMP2 | c.565G>A p.G189R | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1216371810, COSV54601462; called by muse, mutect2, varscan2
- MMP26 | c.750T>G p.H250Q | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV56172310; called by muse, mutect2, varscan2
- MN1 | c.3191A>G p.D1064G | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as rs777577575, COSV100179619; called by mutect2, varscan2
- MN1 | c.1431G>A p.M477I | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV56558446; called by muse, mutect2, varscan2
- MOB2 | c.373T>C p.F125L | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100326421; called by muse, mutect2, varscan2
- MOGAT2 | c.788G>A p.G263D | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1334139523, COSV52219698; called by muse, mutect2
- MOV10 | c.1396C>T p.R466C | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.676); catalogued as rs755646925, COSV62491432; called by mutect2, varscan2
- MPRIP | c.1876G>A p.D626N | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs768965649, COSV100505450, COSV57927318; called by muse, mutect2, varscan2
- MRC1 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 41/164 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.952); catalogued as rs782704717; called by muse, mutect2, varscan2
- MRGPRX3 | c.571C>A p.L191I | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV101283470; called by muse, mutect2, varscan2
- MRI1 | c.988del p.H330Tfs*24 (on ENST00000040663 / NM_001031727.4; = p.H283Tfs*24 on NM_032285.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 14/47 reads (30%) | catalogued as rs751646149; called by mutect2, pindel, varscan2
- MROH6 | c.1718C>T p.A573V | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.225); catalogued as COSV67338757; called by muse, mutect2, varscan2
- MST1 | c.609C>T p.A203= | Splice Region (SNP) | VAF 13/32 reads (41%) | catalogued as rs202238357, COSV99610989; called by muse, mutect2, varscan2
- MTFMT | c.1015T>A p.S339T | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV54977975; called by muse, mutect2, varscan2
- MTHFD2L | c.467G>A p.R156Q (on ENST00000395759 / NM_001144978.2; = p.R98Q on NM_001004346.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); catalogued as rs761954094, COSV57467431; called by muse, mutect2, varscan2
- MTM1 | c.1331G>A p.C444Y | Missense Mutation (SNP) | VAF 62/115 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM990878, COSV60335078; called by muse, mutect2, varscan2
- MTO1 | c.1911A>T p.K637N (on ENST00000370300 / NM_133645.3; = p.K612N on NM_012123.4) | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV64773879; called by muse, mutect2, varscan2
- MTPAP | c.1267C>T p.R423C | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as rs1429255061, COSV53932746; called by muse, varscan2
- MTRF1 | c.1130G>A p.G377E | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV65263338; called by muse, mutect2, varscan2
- MTRF1 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV99520847; called by muse, mutect2
- MTRF1L | c.322A>T p.T108S | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.68); PolyPhen benign (0.082); catalogued as COSV65873397; called by muse, mutect2, varscan2
- MTX3 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.517); catalogued as COSV72512302; called by muse, mutect2, varscan2
- MUC16 | c.39725G>A p.R13242H | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated, low confidence (0.72); PolyPhen probably damaging (0.928); catalogued as rs543370542, COSV66692131; called by muse, mutect2, varscan2
- MUC16 | c.28537C>T p.H9513Y | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV67467492; called by muse, mutect2, varscan2
- MUC16 | c.27554C>T p.T9185I | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); catalogued as COSV67467496; called by muse, mutect2, varscan2
- MUC16 | c.26045T>C p.L8682P | Missense Mutation (SNP) | VAF 71/220 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.211); catalogued as COSV101197512; called by muse, mutect2, varscan2
- MUC17 | c.9698C>T p.P3233L | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs201766687, COSV60289205; called by muse, mutect2, varscan2
- MUC4 | c.15349T>A p.C5117S (on ENST00000463781 / NM_018406.7; = p.C881S on NM_004532.6) | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.234); catalogued as COSV57781097; called by muse, mutect2, varscan2
- MXRA5 | c.2372G>A p.R791H | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs41297261, COSV54235710; called by mutect2, varscan2
- MYCBP2 | c.5600del p.N1867Tfs*9 (on ENST00000357337; = p.N1905Tfs*9 on NM_015057.5) | Frame Shift Del (DEL) | VAF 13/91 reads (14%) | catalogued as COSV62026992; called by mutect2, pindel, varscan2
- MYH14 | c.1337C>T p.A446V | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51818421; called by muse, mutect2, varscan2
- MYH6 | c.3514G>A p.E1172K | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs770838698, COSV100676189; called by muse, mutect2, varscan2
- MYH7 | c.3508G>A p.E1170K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs750627218; called by mutect2, varscan2
- MYH7B | c.3527C>T p.A1176V | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as rs1437073420, COSV53420257; called by muse, mutect2, varscan2
- MYH7B | c.5204A>T p.E1735V | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1300586173, COSV52680081; called by muse, mutect2, varscan2
- MYH9 | c.4220C>T p.A1407V | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.15); catalogued as COSV53386467; called by muse, mutect2, varscan2
- MYH9 | c.2305G>A p.A769T | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53386477; called by muse, mutect2, varscan2
- MYO18A | c.676C>T p.R226W | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62866618; called by muse, mutect2, varscan2
- MYO7A | c.3856G>A p.A1286T | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.996); catalogued as rs727503328, COSV68684663; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO9B | c.724G>A p.G242S | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750177541, COSV68279227; called by muse, mutect2, varscan2
- MYOG | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.346); catalogued as COSV54095617; called by muse, mutect2, varscan2
- NAB1 | c.543del p.A182Rfs*34 | Frame Shift Del (DEL) | VAF 20/63 reads (32%) | catalogued as COSV61608953; called by mutect2, pindel, varscan2
- NAB1 | c.766T>C p.Y256H | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61608772; called by muse, mutect2, varscan2
- NCAPH | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV53636528; called by muse, mutect2, varscan2
- NCK2 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs780151498, COSV51891502; called by muse, mutect2, varscan2
- NCOR2 | c.5415_5420del p.D1807_R1808del | In Frame Del (DEL) | VAF 10/35 reads (29%) | catalogued as rs1396764667; called by mutect2, pindel, varscan2
- NDST4 | c.1571G>C p.G524A | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.668); catalogued as COSV52115462, COSV52120354; called by muse, mutect2, varscan2
- NEK6 | c.811G>A p.G271R | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.156); catalogued as rs779084313, COSV57217972; called by muse, mutect2
- NEMF | c.1352A>G p.Q451R | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV53591699; called by muse, mutect2, varscan2
- NEO1 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769006214, CM1511643, COSV56069878; called by muse, mutect2, varscan2
- NFATC2 | c.212C>A p.P71Q | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.961); catalogued as COSV101043457; called by muse, mutect2, varscan2
- NHLH1 | c.91G>A p.G31S | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV57483644; called by muse, mutect2, varscan2
- NIPAL3 | c.491G>A p.G164D | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV50232072; called by muse, mutect2, varscan2
- NIPBL | c.4261C>T p.P1421S | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs1020113396, COSV56951673; called by muse, mutect2, varscan2
- NISCH | c.3134A>T p.E1045V | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV61900042; called by muse, mutect2, varscan2
- NKD1 | c.862dup p.R288Pfs*12 | Frame Shift Ins (INS) | VAF 18/96 reads (19%) | catalogued as rs772439983; called by mutect2, varscan2
- NKX2-2 | c.385C>T p.R129* | Nonsense Mutation (SNP) | VAF 23/58 reads (40%) | catalogued as CM1210474, COSV101010466; called by muse, mutect2, varscan2
- NKX2-3 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV60728661; called by muse, mutect2, varscan2
- NLE1 | c.1264T>G p.W422G | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99338583; called by muse, mutect2, varscan2
- NLGN2 | c.1282C>T p.R428W | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1305067585, COSV57209246; called by muse, mutect2, varscan2
- NLRC4 | c.1538A>T p.Y513F | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0.069); catalogued as COSV61592753; called by muse, mutect2, varscan2
- NLRP5 | c.794C>T p.T265M | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs755561003, COSV66764648; called by mutect2, varscan2
- NLRP6 | c.1729C>T p.R577W | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV56459777; called by muse, mutect2, varscan2
- NMNAT1 | c.571A>G p.N191D | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.527); catalogued as COSV65882636; called by muse, mutect2, varscan2
- NMT1 | c.1332+2T>A p.X444_splice | Splice Site (SNP) | VAF 17/58 reads (29%) | catalogued as COSV51959794; called by muse, mutect2, varscan2
- NOP58 | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51896705; called by muse, mutect2, varscan2
- NOXA1 | c.872C>A p.P291H | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV100395419; called by muse, mutect2
- NPAS4 | c.1900C>T p.R634C | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as rs775276233, COSV100214718; called by muse, mutect2, varscan2
- NPHP4 | c.1163T>C p.M388T | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs1161460046, COSV65393455, COSV65394998; called by muse, mutect2, varscan2
- NPM1 | c.81A>T p.K27N | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as COSV51559368; called by muse, mutect2, varscan2
- NRXN2 | c.4133G>A p.R1378H | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV99632166; called by muse, mutect2, varscan2
- NSD3 | c.3929G>A p.R1310Q | Missense Mutation (SNP) | VAF 96/323 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs758159008, COSV57668593; called by muse, mutect2, varscan2
1,220 further variants in this file (681 protein-altering or splice-affecting, 503 silent, 36 other) are not listed here.
